Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HQ, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HQ-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F Service: Received:
Reported:
Submitting Physicians:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
RETROPERITONEAL MASS.

SPECIMEN TYPE(S):
A: RETROPERITONEAL MASS FS

FINAL DIAGNOSIS:
A. RETROPERITONEAL MASS, RESECTION:
Leiomyosarcoma, high grade (see comment).
Tumor size: 6.5 cm in greatest dimension.
Tumor necrosis: Less than 5%.
Surgical margins: Free of tumor (closest negative medial, anterior, and posterior margin less than 1 mm).

COMMENT: This is a spindle cell malignant neoplasm arranged in dissecting fascicles with eosinophilic cytoplasm. There are multiple areas of severe cytological atypia, increased mitotic activity (more than 10 mitoses per 10 high powered fields) and tumor necrosis. Immunohistochemical studies done at on block A4 with appropriate controls. The tumor cells are strongly positive for vimentin, desmin, actin and smooth muscle myosin, but negative for CD117. The above findings support the above diagnosis. The tumor cells are also positive for ER (more than 5%), but negative for PR.

reportable

ICD-O-3
Leiomyosarcoma NOS 8890/3
Site: Retroperitoneum C48.0
J 4/22/14

I, MD, PhD the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically signed out by

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:
FSA1. Surgical margin is negative.

This frozen section diagnosis was communicated to Dr. in OR

I, M.D., have performed the intraoperative consultation and issued the above diagnoses.

GROSS DESCRIPTION:
A. The specimen is received fresh labeled "retroperitoneal mass." The specimen consists of an irregular tan-yellow fragment of fibroadipose tissue, measuring 8.0 x 6.0 x 4.5 cm. The specimen has been oriented by the surgeon as follows: suture

[page 2 of 2]
designates left lateral margin. The specimen is inked as follows:

Left lateral margin: Red
Right lateral margin: Yellow
Superior margin: Black
Inferior margin: Blue
Anterior margin: Green
Posterior margin: Orange

The external surface is smooth, tan-yellow and multilobulated. The specimen is serially sectioned to reveal an ovoid multilobulated tan-white to tan-pink nodule, measuring 6.5 x 5.5 x 4.2 cm. The nodule is located at 0.1 cm from closest posterior, anterior, and left medial margin of resection. The nodule is well defined by a thin fibroconnective capsule. There are areas of hemorrhage present. Areas of necrosis and cystic degeneration are not grossly identified. Representative fresh tissue is submitted to

Representative sections are submitted as follows:

FS#1: Perpendicular section left medial margin of resection
A1: Perpendicular section right lateral margin of resection
A2: Perpendicular section superior margin of resection
A3: Perpendicular section inferior margin of resection
A4: Perpendicular section nodule in relation to anterior margin of resection
A5: Perpendicular section nodule in relation to posterior margin of resection
A6-A16: Nodule, random sections

Source: NCI Genomic Data Commons file 85bc1bf1-92b3-4c05-9004-63ceb6494b22 (TCGA-3B-A9HQ.7C1AC157-ACFB-4D1C-981D-C7D67B6B6984.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).